Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A7CG, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A7CG-01A (Primary Tumor).

[page 1 of 2]
Name: [REDACTED]
Address: [REDACTED]

MR No.: [REDACTED]
Service: [REDACTED]
Surgeon: [REDACTED]

Surg. Path. No.: [REDACTED]

DOB: [REDACTED]

Sex/Race: [REDACTED]

Location: [REDACTED]

Taken/Received: [REDACTED]

DIAGNOSIS

UTERUS, CERVIX, BIOPSY (FS1)
- INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY
DIFFERENTIATED, FOCALLY KERATINIZING

UTERUS, CERVIX, BIOPSY
- INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY
DIFFERENTIATED, FOCALLY KERATINIZING

By this signature, I attest that the
above diagnosis is based upon my
personal examination of the slides
(and/or other material indicated in
the diagnosis), and that I have
reviewed and approved this report.

SPECIMEN(S) SUBMITTED

Part 1: 6 O'CLOCK BIOPSY OF CERVIX
Part 2: CERVIX

ICD-O-3
Carcinoma, squamous cell NOS
Site Cervix NOS
C53.9
8/27/13

HISTORY

The patient is a [REDACTED] year old woman with a history of abnormal pap
smears. Coloposcopy showed invasive carcinoma. Operative
procedure: Cervical biopsy.

FROZEN

FS1: 6 o'clock, biopsy of cervix - "Invasive squamous cell
carcinoma." by [REDACTED]

GROSS

The specimens are received in two containers, each labelled with
the patient's name. The specimen is received in a container of
formalin and "cervix biopsy." It consists of three fragments of

[page 2 of 2]
[REDACTED]

Name: [REDACTED]

GROSS (continued)

tan-gray, soft, mucosal tissue measuring 0.6 x 0.5 x 0.2 cm. in aggregate. Inked and wrapped. Labelled A. Jar 0. ([REDACTED]).

The second specimen is received fresh in a container, and "FS1." It consists of three tan-white tissue fragments measuring from 0.3 to 0.4 cm. in greatest dimensions. Wrapped in filter paper. Labelled FS1. Jar 0. [REDACTED]

COMMENT

Microscopic examination substantiates the above cited diagnosis.
[REDACTED]

{End of Report}

Source: NCI Genomic Data Commons file c945dc63-238c-41a0-bcce-75c8b0b1b479 (TCGA-C5-A7CG.E511E773-AAEF-4685-AC83-3EF5F31C489F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).